CPTAC case C3N-03202 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/837ed611-5452-4918-a04b-e6e46413a8f1

Demographics
Sex at birth: male; Race: asian; Year of birth: 1949; Vital status: Dead; Days to death: 1,305 days (3.6 years); Year of death: 2021; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 68.3 years (24,932 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA2; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,305 days (3.6 years); Progression or recurrence: yes; Days to recurrence: 736 days (2.0 years); Days to last follow up: 1,234 days (3.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.6 cm (a second GDC size field records 5.2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 342 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 756 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 756 days (2.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 736 days (2.0 years); Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,122 days (3.1 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,234 days (3.4 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 70 kg; Height: 171 cm; BMI: 23.94; FEV1/FVC before bronchodilator (%): 95.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Cigarettes per day: 10; Tobacco smoking onset year: 1977; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 45.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03202-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 100 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03202-21: Section location: Right Upper Lobe; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3N-03202-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 100 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03202-22: Section location: Right Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3N-03202-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 100 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 17 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03202-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
